CPTAC case C3N-00494 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/239a5fbb-0145-46f6-8ec3-2a96a04011dd

Demographics
Sex at birth: male; Race: white; Year of birth: 1950; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 66.0 years (24,122 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,786 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,786 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm (a second GDC size field records 5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 472 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 702 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,123 days (3.1 years); Disease response: Tumor Free.
- Days to follow up: 1,568 days (4.3 years); Disease response: Complete Response.
- Days to follow up: 1,568 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,786 days (4.9 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 94 kg; Height: 165 cm; BMI: 34; Diabetes treatment type: Insulin.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 84; Cigarettes per day: 40; Tobacco smoking onset year: 1974; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 48.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00494-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 212 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00494-21: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3N-00494-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 252 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00494-22: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 15.
- Sample C3N-00494-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 256 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00494-23: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3N-00494-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 250 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00494-24: Section location: Upper pole; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-00494-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 270 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00494-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
